Somatic mutation profile of tumor specimen 0DTFRL from CCDI case PBCFCU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 13.3 years (4,854 days).
Specimen 0DTFRL: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1221970-ca13-4288-ad36-8d60a0354939.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFRT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63cd8e53-663f-4b4a-aad8-b8a2ceea8cb2

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA0930 | c.256G>T p.D86Y (on ENST00000336156 / NM_001009880.2; = p.D91Y on NM_015264.2) | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52662986; called by muse, mutect2
- FAM9C | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- ZNF696 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SLC22A15 | c.186T>C p.G62= | Silent (SNP) | VAF 110/356 reads (31%) | called by muse, mutect2, varscan2
- CEP57 | c.700-91G>T | Intron (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- STRA6 | c.1300+55_1300+68del | Intron (DEL) | VAF 43/114 reads (38%) | called by mutect2, pindel, varscan2
